Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A41A, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A41A-01A (Primary Tumor).

Procurement Date: . Laterality: Malignant melanoma (Spindle cell) with superficial ulceration.
Breslow's depth is 7 mm.

Path Report: SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin, facial

Tumor size: 1.2 x 0 x 2.5 cm

Tumor features: Ulcerated, Pigmented

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade: Not specified

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Breslow's depth is 7 mm.

ICD O-3

melanoma, spindle cell, NOS
877213

Site: path-skin, face c44.3
CQCF-skin, face c44.3

7-20-12 ep

Source: NCI Genomic Data Commons file a9db38c5-604c-4da0-b85d-5a9319718c67 (TCGA-EB-A41A.C9E916B1-F244-483F-8627-4596CD27B6F8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).